Somatic mutation profile of tumor specimen ALCH-B1X7-TTP1-A (aliquot ALCH-B1X7-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B1X7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.4 years (22,051 days).
Specimen ALCH-B1X7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93ea4644-9ba5-4c25-b366-e4bb5435d2dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1X7-NB1-A (Blood Derived Normal), aliquot ALCH-B1X7-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad94164d-eced-4856-bd39-6b55ee2afdff

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 4, Nonsense Mutation 3, 5'Flank 2, Translation Start Site 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 32/669 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs767145470, COSV57895322; called by muse, mutect2
- DOCK5 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 53/424 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs779896727; called by muse, mutect2, varscan2
- KLK10 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs781235008, COSV100010883; called by muse, mutect2, varscan2
- RECK | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.9); catalogued as rs372609725; called by muse, mutect2, varscan2
- TCEA2 | c.460+1G>T p.X154_splice | Splice Site (SNP) | VAF 30/195 reads (15%) | catalogued as COSV58658164; called by muse, mutect2, varscan2
- TGM7 | c.1062C>A p.Y354* | Nonsense Mutation (SNP) | VAF 41/337 reads (12%) | catalogued as rs777581433; called by muse, mutect2, varscan2
- ARHGAP35 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 58/463 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CACNA2D1 | c.1407A>G p.I469M | Missense Mutation (SNP) | VAF 85/838 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CCDC150 | c.2150G>A p.G717D | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- DNHD1 | c.644T>G p.L215R | Missense Mutation (SNP) | VAF 40/498 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HDDC2 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 82/456 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- HJURP | c.1480G>C p.A494P | Missense Mutation (SNP) | VAF 58/508 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IL12RB2 | c.1623G>A p.W541* | Nonsense Mutation (SNP) | VAF 111/725 reads (15%) | called by muse, mutect2, varscan2
- KCNU1 | c.1661T>A p.L554* | Nonsense Mutation (SNP) | VAF 87/531 reads (16%) | called by muse, mutect2, varscan2
- MEIOC | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAMPT | c.963_964del p.L322Kfs*8 | Frame Shift Del (DEL) | VAF 32/245 reads (13%) | called by pindel, varscan2
- NDUFAF7 | c.1015del p.Y339Ifs*10 | Frame Shift Del (DEL) | VAF 92/751 reads (12%) | called by mutect2, pindel, varscan2
- PAMR1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 55/429 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDZD8 | c.1086_1092del p.S362Rfs*6 | Frame Shift Del (DEL) | VAF 35/345 reads (10%) | called by mutect2, pindel
- PPTC7 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 88/513 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SCN9A | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.068); called by muse, mutect2
- SETD2 | c.3041del p.G1014Vfs*2 | Frame Shift Del (DEL) | VAF 64/402 reads (16%) | called by mutect2, pindel, varscan2
- DPP7 | c.348C>T p.F116= | Silent (SNP) | VAF 32/174 reads (18%) | called by muse, mutect2, varscan2
- FLRT2 | c.1623T>C p.F541= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2
- HRH3 | c.987C>A p.S329= | Silent (SNP) | VAF 36/183 reads (20%) | called by muse, mutect2, varscan2
- LRRC4C | c.595T>C p.L199= | Silent (SNP) | VAF 42/658 reads (6%) | called by muse, mutect2
- MASP1 | c.1881G>A p.R627= | Silent (SNP) | VAF 106/653 reads (16%) | catalogued as rs370248178; called by muse, mutect2, varscan2
- NT5DC3 | c.876C>T p.G292= | Silent (SNP) | VAF 46/335 reads (14%) | called by muse, mutect2, varscan2
- SLC16A5 | c.105C>T p.G35= | Silent (SNP) | VAF 67/484 reads (14%) | called by muse, mutect2, varscan2
- ERLIN2 | chr8:37736213 C>G | 5'Flank (SNP) | VAF 35/228 reads (15%) | called by muse, mutect2, varscan2
- NACA | c.634-18dup | Intron (INS) | VAF 15/129 reads (12%) | called by mutect2, pindel, varscan2
- SYCE1 | chr10:133567900 G>A | 5'Flank (SNP) | VAF 10/114 reads (9%) | catalogued as rs1424075426, COSV58215874; called by muse, mutect2
